Somatic mutation profile of tumor specimen TCGA-KK-A6E0-01A (aliquot TCGA-KK-A6E0-01A-11D-A30X-08) from TCGA case TCGA-KK-A6E0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,700 days).
Specimen TCGA-KK-A6E0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfd2ac3e-e46b-4fa2-977c-21d82d9a3bb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E0-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E0-11A-11D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed8471ee-2b40-4535-85c2-304267df6688

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 12, Silent 11, Frame Shift Del 4, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 34/116 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANXA2R | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as COSV59215347; called by muse, mutect2, varscan2
- ARHGAP26 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV50844027; called by muse, mutect2, varscan2
- ATP13A5 | c.3122G>T p.S1041I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60876626; called by muse, varscan2
- BICD1 | c.230T>C p.F77S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs1014050024, COSV55689705; called by muse, mutect2
- FAM71B | c.1005C>A p.N335K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs924298041, COSV57231851; called by muse, mutect2, varscan2
- GTF3C5 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV59602280; called by muse, mutect2, varscan2
- LCT | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51558858; called by muse, mutect2
- PRAMEF6 | c.1378G>C p.D460H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1439485314; called by mutect2, varscan2
- RFC3 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs140507898, COSV66297134; called by muse, mutect2, varscan2
- SAMM50 | c.1282del p.A428Pfs*39 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as rs1460012287, COSV63109570; called by mutect2, pindel, varscan2
- TMEM87B | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV51719235; called by muse, mutect2, varscan2
- USH2A | c.4958G>A p.R1653Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372436408; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBTB2 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV57314418; called by muse, mutect2, varscan2
- BCL2L13 | c.435del p.H146Mfs*22 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- FOXL2NB | c.432_437del p.E147_R148del | In Frame Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- IFT81 | c.1470del p.K492Nfs*17 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- MIS12 | c.473del p.F158Sfs*21 | Frame Shift Del (DEL) | VAF 62/220 reads (28%) | called by mutect2, pindel, varscan2
- RAD21 | c.30_41del p.R11_L14del | In Frame Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- APOBEC4 | c.228T>A p.G76= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV58018770; called by mutect2, varscan2
- ASB1 | c.793C>T p.L265= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV52828575; called by muse, mutect2, varscan2
- CPED1 | c.1326A>C p.L442= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV60014909; called by muse, mutect2, varscan2
- HMCN1 | c.10359C>T p.T3453= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV54948078; called by muse, mutect2, varscan2
- KRT15 | c.1002C>T p.I334= | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as rs949153676, COSV54179226, COSV54179345; called by muse, mutect2, varscan2
- MRTFA | c.1104C>G p.L368= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV62937522; called by muse, varscan2
- PUM2 | c.2073T>G p.P691= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV57586098; called by muse, mutect2, varscan2
- SHANK1 | c.762C>T p.A254= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs748094229, COSV53249850; called by muse, mutect2, varscan2
- SLC5A12 | c.654A>G p.T218= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV54825640; called by muse, mutect2, varscan2
- VCPIP1 | c.15G>T p.P5= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60050414; called by mutect2, varscan2
- ZBTB7A | c.243C>T p.S81= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV59329429; called by muse, mutect2, varscan2
